Somatic mutation profile of tumor specimen 0DEP26 from CCDI case PBBPSZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.6 years (6,803 days).
Specimen 0DEP26: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d73f4e67-0f6b-4d4d-813b-042e53e82de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEP2A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9408b0d-5296-4f41-9895-6b6596cd3b03

The open-access MAF lists 17 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 2, 3'Flank 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1A3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 318/872 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs397514652, CM132959, COSV60900963; ClinVar: pathogenic; called by muse, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 340/963 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIGK | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 71/1227 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs775603566; called by muse, mutect2
- RPE65 | c.938A>T p.H313L | Missense Mutation (SNP) | VAF 424/1182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM074489; called by muse, mutect2, varscan2
- SLIT3 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 217/636 reads (34%) | catalogued as rs751691883; called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 32/847 reads (4%) | called by muse, mutect2
- DDX23 | c.620-1G>A p.X207_splice | Splice Site (SNP) | VAF 32/726 reads (4%) | called by muse, mutect2
- KLHL2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 40/1200 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- NPPB | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 100/1324 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD24 | c.1965C>T p.Y655= | Silent (SNP) | VAF 44/661 reads (7%) | catalogued as rs756543047, COSV53672657; called by muse, mutect2
- CYP19A1 | c.537C>G p.T179= | Silent (SNP) | VAF 455/1119 reads (41%) | called by muse, mutect2, varscan2
- KLHL2 | c.699G>C p.V233= | Silent (SNP) | VAF 51/1884 reads (3%) | called by muse, mutect2
- PRPF8 | c.1215C>T p.L405= | Silent (SNP) | VAF 31/1148 reads (3%) | called by muse, mutect2
- TTC21B | c.1434C>T p.I478= | Silent (SNP) | VAF 44/1324 reads (3%) | catalogued as rs1337958802; called by muse, mutect2
- ZNF281 | c.12C>T p.G4= | Silent (SNP) | VAF 244/493 reads (49%) | called by muse, mutect2, varscan2
- PLOD2 | c.1501-37A>G | Intron (SNP) | VAF 16/258 reads (6%) | called by muse, mutect2
- TCHHL1 | chr1:152079629 G>T | 3'Flank (SNP) | VAF 302/910 reads (33%) | called by mutect2, varscan2
